Somatic mutation profile of tumor specimen TCGA-DX-A8BH-01A (aliquot TCGA-DX-A8BH-01A-11D-A37C-09) from TCGA case TCGA-DX-A8BH, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 87.0 years (31,770 days).
Specimen TCGA-DX-A8BH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76c36b79-4fd0-4f6b-8119-1423ecdfb149.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A8BH-11A (Solid Tissue Normal), aliquot TCGA-DX-A8BH-11A-43D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3cafd225-e337-4b68-8c08-f045c7f9a4d8

The open-access MAF lists 53 somatic variants for this specimen: 40 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 10, Nonsense Mutation 3, Splice Site 2, Intron 2, Frame Shift Del 1, Splice Region 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.559+1G>A p.X187_splice | Splice Site (SNP) | VAF 11/28 reads (39%) | hotspot (GDC flag); catalogued as rs1131691042, CS137624, COSV52670017, COSV52686439, COSV52695669; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ASCC2 | c.439G>C p.G147R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100316485; called by muse, mutect2
- ASRGL1 | c.22C>T p.H8Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100078127; called by mutect2, varscan2
- ATG2B | c.2201A>C p.H734P | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.188); catalogued as COSV100738213; called by muse, mutect2, varscan2
- BHLHE23 | c.595G>A p.A199T (on ENST00000370346; = p.A215T on NM_080606.4) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as rs776194669, COSV100947628; called by muse, varscan2
- CARMIL3 | c.3976G>A p.V1326I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.059); catalogued as COSV99393718; called by muse, mutect2
- CARS1 | c.1577A>G p.N526S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99543452; called by muse, mutect2, varscan2
- CFAP58 | c.2449A>G p.N817D | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100866161; called by muse, varscan2
- CLCA2 | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.133); catalogued as COSV100991717; called by muse, mutect2, varscan2
- DSCAM | c.5890C>A p.Q1964K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.054); catalogued as COSV101261414; called by muse, mutect2, varscan2
- DSPP | c.3530G>A p.S1177N | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.094); catalogued as rs1431573738, COSV99217941; called by muse, mutect2, varscan2
- FRK | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs766438209, COSV73383799; called by muse, mutect2, varscan2
- G6PC2 | c.873C>A p.S291R | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.178); catalogued as rs1414397570, COSV56371459, COSV99960887; called by muse, mutect2, varscan2
- GRIK3 | c.787-1G>A p.X263_splice | Splice Site (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100902282; called by muse, mutect2, varscan2
- GRM5 | c.772G>C p.D258H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100554260, COSV59609032; called by muse, mutect2, varscan2
- GTF3C5 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100565541; called by muse, mutect2, varscan2
- HIVEP3 | c.4381A>T p.K1461* | Nonsense Mutation (SNP) | VAF 14/78 reads (18%) | catalogued as COSV99913833; called by muse, mutect2, varscan2
- HPD | c.778G>A p.G260R | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs755816788, COSV100000014, COSV56642104; called by muse, mutect2, varscan2
- IFT52 | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100887669; called by muse, mutect2, varscan2
- ITGB6 | c.1918C>G p.Q640E | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99324969; called by muse, mutect2, varscan2
- KCNQ2 | c.1224C>A p.D408E (on ENST00000359125 / NM_172107.4; = p.D398E on NM_004518.6) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1060503977, COSV100610506, COSV60547846; called by muse, mutect2, varscan2
- KRTAP10-11 | c.704C>A p.S235Y | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100554518, COSV100555345; called by muse, mutect2, varscan2
- MAP3K19 | c.3819G>T p.M1273I | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.11); catalogued as COSV100209204; called by muse, mutect2
- MS4A14 | c.91C>T p.H31Y | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.922); catalogued as COSV100279746; called by muse, mutect2, varscan2
- MUC1 | c.3670C>T p.R1224C (on ENST00000611571 / NM_001371720.1; = p.R235C on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs572153326, COSV58111868; called by muse, mutect2, varscan2
- NEFM | c.1398G>T p.K466N | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV99647546; called by muse, mutect2, varscan2
- NTN4 | c.1630G>C p.V544L | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); catalogued as COSV100643865; called by muse, mutect2, varscan2
- OR4A47 | c.614G>T p.C205F | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs748968864; called by muse, varscan2
- PDCD4 | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | catalogued as COSV99701159; called by muse, mutect2
- RBFOX1 | c.1089G>T p.L363F | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.212); catalogued as COSV100303397; called by muse, mutect2, varscan2
- SEMA3A | c.453G>A p.E151= | Splice Region (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99547846; called by muse, mutect2
- SETDB2 | c.869C>T p.T290I | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1332513911, COSV99320986; called by muse, mutect2
- SHANK3 | c.4784G>T p.G1595V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV99437841; called by muse, mutect2
- SIPA1L2 | c.4487G>A p.R1496K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV53392541, COSV99479530; called by muse, mutect2, varscan2
- TENT5D | c.962T>C p.I321T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100382952; called by muse, mutect2, varscan2
- TTN | c.23015G>T p.R7672L (on ENST00000591111; = p.R6745L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | PolyPhen possibly damaging (0.796); catalogued as COSV100627763, COSV60416301; called by muse, mutect2, varscan2
- VAV1 | c.1739T>A p.L580Q | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100409446; called by muse, mutect2, varscan2
- ZPBP | c.588G>C p.Q196H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99250417; called by muse, mutect2, varscan2
- FBRS | c.1017dup p.E340* (on ENST00000287468; = p.E860* on NM_001105079.3) | Frame Shift Ins (INS) | VAF 7/40 reads (18%) | called by mutect2, varscan2
- SLITRK3 | c.2245del p.Q749Kfs*44 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- AC037459.1 | c.219C>T p.D73= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs774073103, COSV99254773; called by muse, mutect2, varscan2
- C7orf31 | c.471C>T p.G157= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs748226356, COSV52217156; called by muse, mutect2, varscan2
- DNAH17 | c.4224G>T p.S1408= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV101103305, COSV67753620; called by muse, mutect2, varscan2
- DNAH8 | c.4218G>A p.K1406= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100547064; called by muse, mutect2, varscan2
- LRP1B | c.120C>T p.H40= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs1221072372, COSV67208120; called by muse, mutect2, varscan2
- LYN | c.1353C>T p.D451= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as rs777296861, COSV101571252; called by muse, varscan2
- OSBPL5 | c.2238C>A p.G746= | Silent (SNP) | VAF 13/129 reads (10%) | catalogued as rs141473758, COSV55144496; called by muse, mutect2
- ROR2 | c.648T>C p.S216= | Silent (SNP) | VAF 31/91 reads (34%) | catalogued as COSV100996087; called by muse, mutect2, varscan2
- ST14 | c.639C>T p.S213= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as COSV99599097; called by muse, mutect2, varscan2
- TUBB2B | c.1260C>A p.S420= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV99455617; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83188G>A | Intron (SNP) | VAF 33/243 reads (14%) | called by muse, mutect2, varscan2
- HBD | chr11:5232783 G>T | 3'Flank (SNP) | VAF 10/65 reads (15%) | catalogued as COSV99496509, COSV99496860; called by muse, mutect2, varscan2
- MBD1 | c.*33-225G>C | Intron (SNP) | VAF 8/35 reads (23%) | catalogued as COSV99497136; called by muse, mutect2, varscan2
